CPTAC case C3N-02183 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4c055580-81e1-48e6-bb81-f607b393b053

Demographics
Sex at birth: female; Race: asian; Year of birth: 1953; Vital status: Dead; Days to death: 340 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 63.6 years (23,246 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 340 days; Progression or recurrence: yes; Days to last follow up: 340 days.
   Pathology details: Greatest tumor dimension: 6 cm.

Follow-up (2 entries)
- Days to follow up: 340 days; Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 248 days; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 401 days (1.1 years); Disease response: With Tumor; Karnofsky performance status: 30; ECOG performance status: 4.

Other clinical attributes
- Weight: 50 kg; Height: 157 cm; BMI: 20.28.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (10 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02183-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 200 mg; Time between excision and freezing: 14 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02183-21: Section location: Right Hemisphere; Percent tumor nuclei: 85; Percent necrosis: 2.
- Samples C3N-02183-02, C3N-02183-03 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 200 mg.
- Samples C3N-02183-31, C3N-02183-32, C3N-02183-72, C3N-02183-73, C3N-02183-74, C3N-02183-75 (6 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-02183-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -3 days; Method of sample procurement: Blood Draw.
